Somatic mutation profile of tumor specimen TCGA-77-7337-01A (aliquot TCGA-77-7337-01A-21D-2042-08) from TCGA case TCGA-77-7337, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 65.9 years (24,065 days).
Specimen TCGA-77-7337-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8686923b-4699-41dd-9c07-5b5a1ff7d729.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-7337-11A (Solid Tissue Normal), aliquot TCGA-77-7337-11A-01D-2042-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d864116a-697d-4d80-ac2d-2374a962cd5b

The open-access MAF lists 375 somatic variants for this specimen: 277 protein-altering or splice-affecting, 87 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 233, Silent 87, Frame Shift Del 16, Nonsense Mutation 13, Splice Site 8, In Frame Del 3, RNA 3, Intron 2, Frame Shift Ins 2, 5'UTR 2, 5'Flank 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.475+1G>T p.X159_splice | Splice Site (SNP) | VAF 18/58 reads (31%) | catalogued as rs81002797, CS083878, CS131767, COSV101204544; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 18/53 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AARS1 | c.2200G>T p.A734S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1225118156, COSV99933685; called by muse, mutect2, varscan2
- AARS1 | c.1468del p.H490Ifs*17 | Frame Shift Del (DEL) | VAF 12/57 reads (21%) | catalogued as rs1441323682; called by mutect2, pindel, varscan2
- ABCC5 | c.2572G>A p.A858T | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV99657304; called by muse, mutect2, varscan2
- AC127029.3 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.969); catalogued as rs371051668, COSV60111188; called by muse, mutect2, varscan2
- ACCSL | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 76/316 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.102); catalogued as COSV101122260; called by muse, mutect2, varscan2
- ACOT2 | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV99469155; called by muse, mutect2, varscan2
- ADAM21 | c.1336T>G p.C446G | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99960514, COSV99961295; called by muse, mutect2, varscan2
- ADAM9 | c.143C>G p.P48R | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101165927, COSV101166216; called by muse, mutect2
- ADAM9 | c.203A>T p.Y68F | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.863); catalogued as COSV101166217; called by muse, mutect2, varscan2
- ADAMTS6 | c.2753G>A p.G918E | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100068518; called by muse, mutect2, varscan2
- ADGRA2 | c.2510C>A p.A837E | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781535229, COSV99605071; called by muse, mutect2
- AK9 | c.5597T>C p.M1866T | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV101413982; called by muse, mutect2, varscan2
- AL645922.1 | c.2416G>A p.G806S | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as COSV100191375; called by muse, mutect2, varscan2
- ANGPT4 | c.436A>T p.I146F | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV101124840; called by muse, mutect2, varscan2
- ANKH | c.1090G>C p.A364P | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99414939, COSV99415545; called by muse, mutect2
- ANKRD33 | c.452A>G p.Q151R (on ENST00000340970 / NM_001304459.2; = p.Q276R on NM_182608.4) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100001460; called by muse, mutect2, varscan2
- ANKS1B | c.411A>T p.Q137H | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100247161, COSV61348606; called by muse, mutect2, varscan2
- AOC1 | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.836); catalogued as COSV100710905; called by muse, mutect2, varscan2
- API5 | c.1128-1G>T p.X376_splice | Splice Site (SNP) | VAF 14/66 reads (21%) | catalogued as COSV101124565; called by muse, mutect2, varscan2
- ARHGAP18 | c.1294A>C p.K432Q | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.045); catalogued as COSV100936404; called by muse, mutect2, varscan2
- ARL15 | c.294A>T p.Q98H | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs1467640062, COSV101544852; called by muse, mutect2, varscan2
- ATP10B | c.500G>A p.W167* | Nonsense Mutation (SNP) | VAF 24/70 reads (34%) | catalogued as COSV100469636; called by muse, mutect2, varscan2
- ATP13A5 | c.1538A>T p.H513L | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV60865606; called by muse, mutect2
- ATP6V1G3 | c.198G>T p.Q66H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.153); catalogued as COSV99810995; called by muse, mutect2, varscan2
- ATP6V1H | c.388T>G p.L130V | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV100778760; called by muse, mutect2
- ATP9A | c.1558G>C p.D520H | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100125434; called by muse, mutect2, varscan2
- BARHL2 | c.460C>G p.L154V | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV100966080; called by muse, mutect2
- BATF2 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 14/63 reads (22%) | catalogued as COSV100101845; called by muse, mutect2, varscan2
- BAX | c.434G>C p.R145P | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); catalogued as COSV99509189; called by muse, mutect2, varscan2
- BRINP3 | c.1695G>C p.L565F | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV100818345, COSV100819197; called by muse, mutect2, varscan2
- C16orf70 | c.595G>T p.E199* | Nonsense Mutation (SNP) | VAF 74/271 reads (27%) | catalogued as COSV99531564; called by muse, mutect2, varscan2
- C2orf80 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.003); catalogued as COSV99050001; called by muse, mutect2, varscan2
- CABP4 | c.526C>A p.H176N | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.628); catalogued as COSV100351614; called by muse, mutect2, varscan2
- CASP1 | c.1075G>T p.E359* (on ENST00000436863 / NM_033292.4; = p.E338* on NM_001223.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/56 reads (11%) | catalogued as COSV99507959; called by muse, mutect2
- CASP1 | c.1074A>T p.Q358H (on ENST00000436863 / NM_033292.4; = p.Q337H on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99507961; called by muse, mutect2, varscan2
- CASP8 | c.551-1G>C p.X184_splice | Splice Site (SNP) | VAF 44/76 reads (58%) | catalogued as COSV51849678; called by muse, mutect2, varscan2
- CCBE1 | c.397C>G p.L133V | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.232); catalogued as COSV101232855; called by muse, mutect2, varscan2
- CD84 | c.818C>A p.A273D (on ENST00000311224 / NM_001184879.2; = p.A256D on NM_003874.4) | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100246207; called by muse, mutect2, varscan2
- CDK15 | c.484G>T p.V162L (on ENST00000652192 / NM_001366386.2; = p.V111L on NM_139158.2) | Missense Mutation (SNP) | VAF 86/137 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99643523; called by muse, mutect2, varscan2
- CDKL4 | c.135G>C p.K45N | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.897); catalogued as COSV101115456; called by muse, mutect2, varscan2
- CEACAM18 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.688); catalogued as COSV67282323, COSV67282587; called by muse, mutect2, varscan2
- CENPH | c.434A>T p.Q145L | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99295608; called by muse, mutect2, varscan2
- CFAP74 | c.386C>A p.A129E | Missense Mutation (SNP) | VAF 27/212 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.905); catalogued as COSV54566768; called by muse, mutect2, varscan2
- CLSTN3 | c.1582G>C p.A528P | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1446478656, COSV99867416; called by muse, mutect2, varscan2
- CNTN6 | c.947-1G>C p.X316_splice | Splice Site (SNP) | VAF 9/44 reads (20%) | catalogued as COSV100611534; called by muse, mutect2, varscan2
- COL19A1 | c.2988C>A p.H996Q | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as COSV100507061; called by muse, mutect2, varscan2
- COL22A1 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100279859; called by muse, mutect2, varscan2
- COL25A1 | c.1753T>A p.Y585N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.334); catalogued as COSV101211600; called by muse, mutect2, varscan2
- COL3A1 | c.4042G>C p.D1348H | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV100483465, COSV100483545, COSV100483712; called by muse, mutect2, varscan2
- CPA3 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV99936373; called by muse, mutect2, varscan2
- CREBBP | c.3925G>C p.D1309H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV52140048, COSV99271146; called by muse, mutect2, varscan2
- CRISPLD1 | c.76G>T p.V26F | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs201056037, COSV100082309; called by muse, varscan2
- CRISPLD1 | c.134A>T p.E45V | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.163); catalogued as COSV100082312; called by muse, varscan2
- CSMD3 | c.7753G>T p.G2585C (on ENST00000297405 / NM_001363185.1; = p.G2481C on NM_052900.3) | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99838074; called by muse, mutect2, varscan2
- CSMD3 | c.6242G>T p.G2081V (on ENST00000297405 / NM_001363185.1; = p.G1977V on NM_052900.3) | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99842935; called by muse, mutect2, varscan2
- CSMD3 | c.5644C>A p.P1882T (on ENST00000297405 / NM_001363185.1; = p.P1778T on NM_052900.3) | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV99842939; called by muse, mutect2, varscan2
- DCC | c.1666G>A p.G556S | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); catalogued as rs771834549, COSV100502050; called by muse, varscan2
- DCC | c.1715A>T p.K572I | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV100502052; called by muse, varscan2
- DCC | c.2013G>T p.M671I | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100502053; called by muse, mutect2, varscan2
- DCDC1 | c.5249G>T p.R1750I (on ENST00000597505 / NM_001367979.1; = p.R857I on NM_020869.3) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100360707; called by muse, mutect2, varscan2
- DCDC1 | c.4396C>T p.R1466C (on ENST00000597505 / NM_001367979.1; = p.R573C on NM_020869.3) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs761430464, COSV100337933, COSV100338441, COSV57998997; called by muse, mutect2, varscan2
- DDR2 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100906778; called by muse, mutect2, varscan2
- DDX23 | c.2395C>T p.P799S | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV56399868, COSV56399973, COSV99975042; called by muse, mutect2, varscan2
- DDX54 | c.2000A>G p.K667R | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs201969897, COSV100014091; called by muse, mutect2, varscan2
- DENND3 | c.1594G>T p.A532S | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV99371435; called by muse, mutect2, varscan2
- DNAJC6 | c.534G>A p.M178I | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as rs760563343, COSV99675408; called by muse, mutect2, varscan2
- DOK6 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748208057, COSV101234838, COSV66935519; called by muse, mutect2, varscan2
- DPP10 | c.1165C>A p.P389T | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100070144, COSV59696397; called by muse, mutect2, varscan2
- DYNC1I1 | c.1082A>G p.Y361C | Missense Mutation (SNP) | VAF 59/182 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100268908; called by muse, mutect2, varscan2
- EML3 | c.1103C>T p.S368L | Missense Mutation (SNP) | VAF 55/238 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1272189379, COSV99606048; called by muse, mutect2, varscan2
- EPHA7 | c.2761G>A p.D921N | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as COSV65191532; called by muse, varscan2
- ERC2 | c.2209G>T p.E737* | Nonsense Mutation (SNP) | VAF 58/167 reads (35%) | catalogued as COSV55607652, COSV99887880; called by muse, mutect2, varscan2
- ESRRG | c.736C>A p.P246T | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100753602; called by muse, mutect2, varscan2
- EVC2 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.024); catalogued as COSV100186517; called by muse, mutect2, varscan2
- FAM78B | c.752G>T p.R251L | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.222); catalogued as COSV100597733; called by muse, mutect2, varscan2
- FARP1 | c.1961G>A p.G654E | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs1265169369, COSV60335989; called by muse, mutect2, varscan2
- FBH1 | c.1993T>A p.C665S (on ENST00000362091 / NM_178150.3; = p.C716S on NM_032807.4) | Missense Mutation (SNP) | VAF 69/172 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100758874; called by muse, mutect2, varscan2
- FMN2 | c.1396G>T p.A466S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.014); catalogued as COSV100146666, COSV60422529, COSV60444349; called by muse, mutect2, varscan2
- FRMD1 | c.152C>A p.S51* | Nonsense Mutation (SNP) | VAF 29/108 reads (27%) | catalogued as COSV99350024; called by muse, mutect2, varscan2
- GABBR2 | c.2122G>T p.A708S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as rs267602049, COSV99411025, COSV99411161; called by muse, mutect2, varscan2
- GABRA2 | c.715del p.V239* | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | catalogued as COSV62916708; called by mutect2, pindel, varscan2
- GABRB3 | c.1090C>A p.H364N | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV54668041; called by muse, mutect2, varscan2
- GDAP1L1 | c.792T>A p.C264* | Nonsense Mutation (SNP) | VAF 47/162 reads (29%) | catalogued as COSV100697641; called by muse, mutect2, varscan2
- GDPD5 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs767614808, COSV100409437; called by muse, mutect2, varscan2
- GPM6A | c.497C>A p.T166K | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.572); catalogued as COSV99704975; called by muse, mutect2, varscan2
- GPR158 | c.1425G>T p.E475D | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.688); catalogued as COSV66278218; called by muse, mutect2, varscan2
- GPR63 | c.719A>T p.Q240L | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV100013514; called by muse, mutect2, varscan2
- GPRIN1 | c.1163T>C p.V388A | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV99991998; called by muse, mutect2, varscan2
- GRIA4 | c.544A>T p.S182C | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV99233571; called by muse, mutect2, varscan2
- GRID2 | c.343C>G p.P115A | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99938517, COSV99944684; called by muse, mutect2, varscan2
- GRM1 | c.3421G>A p.D1141N | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.031); catalogued as COSV51108598; called by muse, mutect2
- GTF3C1 | c.3953G>T p.R1318L | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100649623; called by muse, mutect2, varscan2
- H2BC3 | c.40G>C p.G14R | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100778310; called by muse, mutect2
- H3C2 | c.100G>T p.G34C | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as COSV52517876, COSV99451654; called by muse, mutect2, varscan2
- ICE1 | c.3715G>C p.E1239Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99665334; called by muse, mutect2, varscan2
- IFNAR2 | c.640C>T p.H214Y | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.394); catalogued as COSV100577148; called by muse, mutect2, varscan2
- IGSF9B | c.2353G>T p.E785* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100318192, COSV58063792; called by muse, mutect2, varscan2
- IL2RB | c.995A>T p.K332M | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99345101; called by muse, mutect2, varscan2
- IL36A | c.417C>G p.I139M | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV52083150, COSV99382181; called by muse, mutect2, varscan2
- ITGAL | c.464T>C p.V155A | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.803); catalogued as COSV100776318; called by muse, mutect2, varscan2
- ITPKA | c.886G>C p.D296H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99541106; called by muse, mutect2, varscan2
- JCAD | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs373768578; called by muse, mutect2, varscan2
- JMJD1C | c.4496C>T p.A1499V | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100550739; called by muse, mutect2, varscan2
- KCNJ3 | c.120G>C p.K40N | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.69); catalogued as COSV54536467, COSV99716273, COSV99716479; called by muse, mutect2, varscan2
- KLHL1 | c.1003A>T p.S335C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as COSV100917869; called by muse, mutect2, varscan2
- KLHL31 | c.329G>C p.R110T | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.412); catalogued as COSV100911838, COSV63882428; called by muse, mutect2, varscan2
- KLHL38 | c.794C>G p.T265S | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV100384518; called by muse, mutect2
- KLHL8 | c.106G>A p.G36S | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV99911527; called by muse, mutect2, varscan2
- KLHL9 | c.1804G>C p.G602R | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100757143; called by muse, mutect2, varscan2
- KMT2A | c.8275G>A p.E2759K | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs782694778, COSV100629452; called by muse, mutect2, varscan2
- KMT2D | c.15964G>A p.G5322R | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99978886, COSV99984622; called by muse, mutect2, varscan2
- KRTAP21-2 | c.38G>T p.C13F | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.69); catalogued as COSV100441244; called by muse, varscan2
- LAMA1 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101057260; called by muse, mutect2, varscan2
- LAMA2 | c.2770G>T p.G924C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101370719; called by muse, mutect2
- LPCAT2 | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV100045160; called by muse, mutect2, varscan2
- LRBA | c.1049C>T p.T350I | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100841964; called by muse, mutect2, varscan2
- LRIF1 | c.1265C>A p.S422Y | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100870894; called by muse, mutect2, varscan2
- LRIT3 | c.967G>C p.A323P | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373408851, COSV59988092; called by muse, mutect2, varscan2
- LRP2 | c.11013C>T p.C3671= | Splice Region (SNP) | VAF 23/113 reads (20%) | catalogued as rs1436494910, COSV99789716; called by muse, mutect2, varscan2
- LRRC37B | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0.006); catalogued as COSV100496428; called by muse, mutect2, varscan2
- LRRC37B | c.1375A>T p.T459S | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.31); catalogued as COSV100496429; called by muse, mutect2, varscan2
- LRRC4B | c.1963C>A p.L655M | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.736); catalogued as COSV100976000; called by muse, mutect2, varscan2
- LRRK2 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 17/78 reads (22%) | catalogued as COSV54158576; called by muse, mutect2, varscan2
- LRRN1 | c.103C>T p.L35F | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.486); catalogued as COSV100076509; called by muse, mutect2, varscan2
- LSG1 | c.778G>C p.D260H | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as COSV99503425; called by muse, mutect2, varscan2
- MADD | c.1100T>A p.L367Q | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100211834; called by muse, mutect2, varscan2
- MAGEA11 | c.126C>G p.F42L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV100290624, COSV60753938, COSV60756234; called by muse, mutect2, varscan2
- MAP1A | c.3904G>A p.G1302R | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.006); catalogued as COSV100289038; called by muse, mutect2, varscan2
- MAP3K19 | c.1544A>T p.N515I | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV100209006; called by muse, mutect2, varscan2
- MAP7 | c.751+1G>T p.X251_splice | Splice Site (SNP) | VAF 24/60 reads (40%) | catalogued as COSV100643978; called by muse, varscan2
- MCM4 | c.86C>A p.A29D | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100031758; called by muse, mutect2, varscan2
- MFAP3L | c.418T>A p.L140M | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100852701; called by muse, mutect2, varscan2
- MIA3 | c.2629A>G p.K877E | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV100719514; called by muse, mutect2
- MME | c.362T>C p.V121A | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.771); catalogued as COSV64706464; called by muse, mutect2, varscan2
- MON2 | c.476A>G p.N159S | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as COSV99743195; called by muse, mutect2, varscan2
- MOSPD2 | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.219); catalogued as COSV99048083; called by muse, mutect2, varscan2
- MYH6 | c.2003A>G p.H668R | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100676862; called by muse, mutect2, varscan2
- MYO16 | c.635G>C p.G212A | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51813694, COSV99193422; called by muse, mutect2, varscan2
- MYO7A | c.4187A>T p.Y1396F | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.99); catalogued as COSV101289229; called by muse, mutect2, varscan2
- NBEA | c.3915A>T p.L1305F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated, low confidence (0.4); PolyPhen probably damaging (0.986); catalogued as COSV100082831; called by muse, mutect2, varscan2
- NCKAP5 | c.3236C>T p.T1079M | Missense Mutation (SNP) | VAF 92/214 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.176); catalogued as rs375896892; called by muse, mutect2, varscan2
- NDUFAF4 | c.272A>C p.K91T | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.046); catalogued as COSV100294114; called by muse, mutect2, varscan2
- NDUFS6 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99929107; called by muse, mutect2, varscan2
- NEB | c.3622A>G p.I1208V | Missense Mutation (SNP) | VAF 121/280 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); catalogued as COSV99426107; called by muse, mutect2, varscan2
- NEXMIF | c.2206G>A p.A736T | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99281464; called by muse, mutect2, varscan2
- NLRP11 | c.166T>A p.L56M | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100789788; called by muse, mutect2, varscan2
- NPAS4 | c.1493A>T p.E498V | Missense Mutation (SNP) | VAF 90/400 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV100215153; called by muse, mutect2, varscan2
- NPHP1 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as COSV100338371, COSV100338555; called by muse, mutect2, varscan2
- NR3C2 | c.2331G>A p.M777I | Missense Mutation (SNP) | VAF 56/186 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs747431684, COSV60993705; called by muse, mutect2, varscan2
- NYNRIN | c.3602G>T p.G1201V | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV101230654; called by muse, mutect2, varscan2
- ODF2L | c.1605-2A>T p.X535_splice (on ENST00000317336; = p.X519_splice on NM_020729.3) | Splice Site (SNP) | VAF 8/31 reads (26%) | catalogued as COSV54016863, COSV99644592; called by muse, mutect2, varscan2
- OR11G2 | c.530G>T p.R177L | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.342); catalogued as rs376091395, COSV62133253; called by muse, mutect2, varscan2
- OR2T34 | c.875C>G p.P292R | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100170477, COSV60900930; called by mutect2, varscan2
- OR2T34 | c.874C>A p.P292T | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as COSV100170478; called by mutect2, varscan2
- OR51A2 | c.569C>A p.A190D | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100985076; called by muse, mutect2, varscan2
- OR52N1 | c.586G>T p.V196F | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as rs758168503, COSV100398713; called by muse, mutect2, varscan2
- OR5D13 | c.674C>A p.T225N | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV100686985, COSV100687071; called by muse, mutect2, varscan2
- OR5D16 | c.202C>G p.L68V | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101004091, COSV65721624; called by muse, mutect2, varscan2
- OR6K3 | c.456G>T p.M152I (on ENST00000368146; = p.M136I on NM_001005327.2) | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV100933875; called by muse, mutect2, varscan2
- OR8B4 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.125); catalogued as COSV100635859; called by muse, mutect2, varscan2
- OTUB2 | c.605C>G p.A202G | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.83); PolyPhen benign (0.04); catalogued as COSV99180201; called by muse, mutect2, varscan2
- P4HA3 | c.401A>T p.E134V | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV100525829; called by muse, mutect2, varscan2
- PANK4 | c.103A>G p.K35E | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV101015643; called by muse, varscan2
- PAPLN | c.1507G>A p.G503S (on ENST00000554301; = p.G476S on NM_173462.4) | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99390192; called by muse, mutect2, varscan2
- PAPSS1 | c.382A>G p.I128V | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99492299; called by muse, mutect2, varscan2
- PCDH10 | c.1807G>T p.V603L | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV52095425, COSV99994221; called by muse, mutect2, varscan2
- PCDH11Y | c.2288G>T p.G763V (on ENST00000400457 / NM_032973.2; = p.G752V on NM_032971.3) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99292286; called by muse, mutect2, varscan2
- PCDHGA5 | c.593A>G p.Q198R | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs1286445808, COSV99543608; called by muse, mutect2, varscan2
- PEG3 | c.552G>T p.R184S | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV55637255, COSV99689913; called by muse, mutect2
- PER3 | c.1048A>T p.I350F | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100728431; called by muse, mutect2, varscan2
- PEX1 | c.975G>C p.E325D | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99952312; called by muse, mutect2, varscan2
- PFAS | c.2533C>G p.P845A | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV100119059; called by muse, mutect2, varscan2
- PHLDB2 | c.1613C>G p.T538S | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV101208607; called by muse, mutect2, varscan2
- PKHD1 | c.7087A>C p.N2363H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100584086; called by muse, varscan2
- PKHD1 | c.6217G>T p.G2073W | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV100580952; called by muse, mutect2, varscan2
- PLCB1 | c.293T>A p.L98Q | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.059); catalogued as COSV100570850, COSV100571797; called by muse, mutect2, varscan2
- PLXNA2 | c.5148G>T p.M1716I | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV100885692; called by muse, mutect2, varscan2
- PLXNA2 | c.5147T>A p.M1716K | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100885693; called by muse, mutect2, varscan2
- PPEF1 | c.1802A>T p.H601L | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100583968; called by muse, mutect2, varscan2
- PPIP5K2 | c.3104C>A p.S1035Y | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); catalogued as COSV100384099; called by muse, mutect2
- PRDM1 | c.654G>C p.M218I | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100958929; called by muse, mutect2, varscan2
- PREX1 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1348321624, COSV64248592; called by muse, mutect2, varscan2
- PRKAG1 | c.937G>T p.V313L | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV100305332; called by muse, mutect2, varscan2
- PRKN | c.920T>C p.L307P | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100630503; called by muse, mutect2, varscan2
- PRR23B | c.792G>T p.Q264H | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV100272170; called by muse, mutect2, varscan2
- PSAPL1 | c.1464C>G p.F488L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV100040610; called by muse, mutect2, varscan2
- PSMD13 | c.864C>A p.H288Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as COSV100728883; called by muse, mutect2, varscan2
- PTPRH | c.3178C>T p.P1060S | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99671319; called by muse, mutect2, varscan2
- PTPRS | c.2379G>T p.E793D | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV99511792; called by muse, mutect2, varscan2
- PYGM | c.133A>T p.N45Y | Missense Mutation (SNP) | VAF 61/273 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.18); catalogued as COSV99377466; called by muse, mutect2, varscan2
- RAD51AP2 | c.3353C>G p.S1118* | Nonsense Mutation (SNP) | VAF 3/25 reads (12%) | catalogued as COSV101208391; called by muse, mutect2
- RFC4 | c.136C>A p.P46T | Missense Mutation (SNP) | VAF 69/158 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99961302; called by muse, mutect2, varscan2
- RINL | c.1466G>A p.R489Q (on ENST00000591812 / NM_001195833.2; = p.R375Q on NM_198445.4) | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.02); catalogued as COSV100531285; called by muse, mutect2, varscan2
- ROBO3 | c.4001G>T p.R1334L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.474); catalogued as rs200381743, COSV100127307; called by muse, mutect2
- RYR3 | c.1795G>C p.D599H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV101213581; called by muse, mutect2, varscan2
- S1PR3 | c.1018A>G p.S340G | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as rs779979202, COSV100822594; called by muse, mutect2, varscan2
- SACS | c.12393G>C p.R4131S | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.728); catalogued as COSV101207590, COSV66534870; called by muse, mutect2, varscan2
- SAP30 | c.178G>T p.G60W | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV99633200; called by muse, mutect2, varscan2
- SCP2D1 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs761177327, COSV53857064; called by muse, mutect2, varscan2
- SEMA6D | c.1120G>T p.G374C | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100317377; called by muse, mutect2, varscan2
- SERBP1 | c.1151G>A p.R384H (on ENST00000370995 / NM_001018067.2; = p.R363H on NM_015640.4) | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs1161015099, COSV100769148; called by muse, mutect2, varscan2
- SHOC1 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as COSV59505663; called by muse, mutect2, varscan2
- SLC17A3 | c.479-2A>T p.X160_splice | Splice Site (SNP) | VAF 5/40 reads (13%) | catalogued as COSV100399355; called by muse, mutect2, varscan2
- SLC2A2 | c.529G>C p.G177R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100049387, COSV100049461; called by muse, mutect2, varscan2
- SLC37A4 | c.170C>A p.S57* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100421593; called by muse, mutect2
- SOX14 | c.497A>T p.Y166F | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV100048303; called by muse, mutect2
- SPATA16 | c.1294C>G p.R432G | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as COSV100651476, COSV63529662; called by muse, mutect2, varscan2
- SPTA1 | c.3227G>A p.R1076H | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.188); catalogued as rs931070390, COSV100934710; called by muse, mutect2, varscan2
- SPTA1 | c.2883G>T p.Q961H | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100935336; called by muse, mutect2, varscan2
- SPTBN2 | c.6553C>T p.R2185W | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs765660173, COSV100020107; called by muse, mutect2, varscan2
- SYNE1 | c.26278G>A p.G8760R (on ENST00000367255 / NM_182961.4; = p.G8712R on NM_033071.3) | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs758464869, COSV99573978; called by muse, mutect2, varscan2
- TAF1 | c.4541A>C p.K1514T (on ENST00000373790 / NM_138923.4; = p.K1535T on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV99336551; called by muse, mutect2, varscan2
- TAFA2 | c.33A>T p.K11N | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.05); catalogued as COSV101353730; called by muse, mutect2, varscan2
- TARDBP | c.1220C>G p.S407C | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); catalogued as rs1433662988, COSV53569642; called by muse, mutect2
- TAS1R1 | c.869C>G p.T290S | Missense Mutation (SNP) | VAF 63/121 reads (52%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100039800; called by muse, mutect2, varscan2
- TAS2R10 | c.746G>T p.C249F | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99555596; called by muse, mutect2, varscan2
- TAS2R7 | c.148A>T p.S50C | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as COSV99553904; called by muse, mutect2, varscan2
- TENM1 | c.5879T>A p.L1960Q | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as COSV100950523; called by muse, mutect2, varscan2
- TGFB3 | c.1017C>G p.Y339* | Nonsense Mutation (SNP) | VAF 11/105 reads (10%) | catalogued as COSV99472653; called by muse, mutect2, varscan2
- THAP1 | c.575A>T p.D192V | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV54273360, COSV99576744; called by muse, mutect2, varscan2
- THAP5 | c.832G>A p.A278T (on ENST00000415914 / NM_001130475.3; = p.A236T on NM_182529.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100542869; called by muse, mutect2, varscan2
- TLR4 | c.1952T>A p.V651D (on ENST00000355622 / NM_138554.5; = p.V611D on NM_003266.4) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100842829; called by muse, mutect2, varscan2
- TMEM132B | c.493C>A p.P165T | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.215); catalogued as COSV100170513, COSV54753966; called by muse, mutect2, varscan2
- TMEM9 | c.446G>T p.R149L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV100947431; called by muse, mutect2, varscan2
- TNFRSF11A | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV99500482; called by muse, mutect2, varscan2
- TRH | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100234907, COSV57015687; called by muse, mutect2, varscan2
- TRIM49 | c.1154A>T p.N385I | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV100316190; called by muse, mutect2
- TRIM51 | c.1228G>C p.G410R | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs534189010, COSV99793026; called by muse, mutect2, varscan2
- TSC1 | c.210+1G>C p.X70_splice | Splice Site (SNP) | VAF 7/22 reads (32%) | catalogued as CS107897, COSV100052309, COSV104404419; called by muse, mutect2, varscan2
- TTC29 | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV100284296; called by muse, mutect2, varscan2
- TTC37 | c.4501A>G p.T1501A | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV100706789; called by muse, mutect2, varscan2
- TTN | c.64631G>A p.R21544Q (on ENST00000591111; = p.R14120Q on NM_003319.4) | Missense Mutation (SNP) | VAF 116/226 reads (51%) | PolyPhen probably damaging (0.996); catalogued as rs201448988; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBAP2L | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.978); catalogued as COSV99671937; called by muse, mutect2, varscan2
- UBQLN3 | c.1291G>T p.G431W | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV100293881; called by muse, mutect2, varscan2
- UBXN10 | c.826G>C p.G276R | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV100907826; called by muse, mutect2, varscan2
- UNC5C | c.58C>A p.L20M | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.969); catalogued as rs1016604244, COSV101497977; called by muse, mutect2, varscan2
- UNC79 | c.7202G>C p.G2401A (on ENST00000393151 / NM_001346218.2; = p.G2224A on NM_020818.5) | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV56416323, COSV99829263; called by muse, mutect2, varscan2
- USH2A | c.916G>T p.G306C | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV100239670; called by muse, mutect2, varscan2
- USP4 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.541); catalogued as COSV99649598; called by muse, varscan2
- VRTN | c.946G>T p.A316S | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56442147, COSV99832405; called by muse, mutect2, varscan2
- WDR33 | c.1792C>A p.P598T | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.431); catalogued as COSV100460481; called by muse, mutect2, varscan2
- WDR70 | c.1621G>C p.E541Q | Missense Mutation (SNP) | VAF 39/237 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.219); catalogued as COSV99459727; called by muse, mutect2, varscan2
- WHRN | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); catalogued as COSV99470522; called by muse, mutect2
- WWC1 | c.449C>A p.S150* | Nonsense Mutation (SNP) | VAF 26/75 reads (35%) | catalogued as COSV99515632; called by muse, mutect2, varscan2
- XYLT1 | c.640G>C p.G214R | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV54476254, COSV99762862; called by muse, mutect2, varscan2
- YBX3 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99685256; called by muse, mutect2, varscan2
- ZBED2 | c.446T>C p.M149T | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs747052026, COSV99343338; called by muse, varscan2
- ZBTB20 | c.1109C>G p.P370R (on ENST00000474710 / NM_001164342.2; = p.P297R on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV100614735; called by muse, mutect2, varscan2
- ZFHX3 | c.7814C>T p.S2605L | Missense Mutation (SNP) | VAF 69/237 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.508); catalogued as COSV99214056; called by muse, mutect2, varscan2
- ZFYVE16 | c.688A>G p.K230E | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV100566585; called by muse, mutect2, varscan2
- ZNF528 | c.1232G>C p.C411S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100846707; called by muse, mutect2, varscan2
- ZNF675 | c.873A>T p.K291N | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100705134; called by muse, mutect2, varscan2
- ZSCAN5B | c.950C>G p.P317R | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.641); catalogued as COSV100627894, COSV100628030; called by muse, mutect2, varscan2
- ACACB | c.4556dup p.M1520Dfs*20 | Frame Shift Ins (INS) | VAF 28/112 reads (25%) | called by mutect2, pindel, varscan2
- ATP6V0D2 | c.734del p.G245Afs*20 | Frame Shift Del (DEL) | VAF 27/92 reads (29%) | called by mutect2, varscan2
- CNN1 | c.646del p.Q216Rfs*4 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | called by mutect2, pindel
- CNTNAP3 | c.3851A>T p.K1284I | Missense Mutation (SNP) | VAF 40/568 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.108); called by muse, mutect2
- CPN1 | c.12_26del p.L5_L9del | In Frame Del (DEL) | VAF 10/54 reads (19%) | called by mutect2, pindel
- EPHA7 | c.2746del p.D916Ifs*40 | Frame Shift Del (DEL) | VAF 15/86 reads (17%) | called by pindel, varscan2
- ERG | c.389del p.R130Pfs*25 | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | called by mutect2, pindel, varscan2
- HECTD4 | c.7651_7678del p.S2551Rfs*13 | Frame Shift Del (DEL) | VAF 24/208 reads (12%) | called by mutect2, pindel
- IGKV1D-13 | c.197C>G p.P66R | Missense Mutation (SNP) | VAF 81/164 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- KMT2D | c.16285_16307del p.T5429Qfs*22 | Frame Shift Del (DEL) | VAF 28/275 reads (10%) | called by mutect2, pindel
- LAMA4 | c.2047del p.A683Qfs*20 (on ENST00000230538 / NM_001105206.3; = p.A676Qfs*20 on NM_002290.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/91 reads (24%) | called by mutect2, pindel, varscan2
- LCT | c.4236_4237del p.P1413Tfs*4 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | called by pindel, varscan2
- MKI67 | c.7974_7976del p.E2660del | In Frame Del (DEL) | VAF 32/160 reads (20%) | called by pindel, varscan2
- MMP25 | c.418del p.V140Sfs*3 | Frame Shift Del (DEL) | VAF 22/87 reads (25%) | called by mutect2, pindel, varscan2
- NBPF26 | c.3343del p.E1115Kfs*41 (on ENST00000620612; = p.E853Kfs*41 on NM_001351372.1) | Frame Shift Del (DEL) | VAF 11/85 reads (13%) | called by pindel, varscan2
- SLC25A6 | c.851del p.G284Afs*14 | Frame Shift Del (DEL) | VAF 51/247 reads (21%) | called by mutect2, pindel, varscan2
- SMG7 | c.2008_2012del p.V670Pfs*161 | Frame Shift Del (DEL) | VAF 28/168 reads (17%) | called by pindel, varscan2
- SPDYC | c.295_296del p.A99Pfs*32 | Frame Shift Del (DEL) | VAF 22/124 reads (18%) | called by pindel, varscan2
- SUPT20HL2 | c.388G>C p.D130H | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, varscan2
- TNFRSF25 | c.264_287del p.E88_C95del | In Frame Del (DEL) | VAF 16/178 reads (9%) | called by mutect2, pindel
- ZDBF2 | c.5487dup p.K1830Efs*11 | Frame Shift Ins (INS) | VAF 25/51 reads (49%) | called by mutect2, pindel, varscan2
- ZNF425 | c.923del p.G308Afs*34 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | called by mutect2, pindel, varscan2
- ACTRT1 | c.519C>T p.S173= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV100947695; called by muse, mutect2, varscan2
- AGFG2 | c.798C>T p.S266= | Silent (SNP) | VAF 43/179 reads (24%) | catalogued as COSV99499472; called by muse, mutect2, varscan2
- AGRN | c.5421G>A p.Q1807= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV101038993; called by muse, mutect2
- AK5 | c.726C>T p.F242= (on ENST00000354567 / NM_174858.3; = p.F216= on NM_012093.4) | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as COSV60983718; called by muse, mutect2, varscan2
- ANO4 | c.1305A>G p.A435= (on ENST00000392977 / NM_001286615.2; = p.A400= on NM_178826.4) | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100153478; called by muse, mutect2, varscan2
- ANO5 | c.2598G>A p.K866= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV100202071; called by muse, mutect2, varscan2
- ATP6V1G3 | c.126A>G p.V42= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV99810737; called by muse, mutect2, varscan2
- BAIAP3 | c.1638C>T p.L546= | Silent (SNP) | VAF 36/134 reads (27%) | catalogued as COSV99136331; called by muse, mutect2, varscan2
- CD2 | c.948G>A p.S316= | Silent (SNP) | VAF 42/164 reads (26%) | catalogued as rs763125368, COSV101040481; called by muse, mutect2, varscan2
- CIITA | c.519G>T p.V173= | Silent (SNP) | VAF 37/155 reads (24%) | catalogued as COSV100162444; called by muse, mutect2, varscan2
- CLEC4C | c.15A>G p.E5= | Silent (SNP) | VAF 38/167 reads (23%) | catalogued as rs999853633, COSV100665532; called by muse, mutect2, varscan2
- CLIC5 | c.567C>A p.G189= (on ENST00000185206 / NM_001370649.1; = p.G30= on NM_016929.5) | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV99485077; called by mutect2, varscan2
- CNGB1 | c.1794C>T p.P598= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV99201886, COSV99206005; called by muse, mutect2
- COL7A1 | c.7335G>T p.P2445= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs779304674, COSV100097159; called by muse, varscan2
- CRACR2A | c.951G>T p.R317= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV99365372; called by muse, mutect2, varscan2
- CRB2 | c.1104G>A p.L368= | Silent (SNP) | VAF 18/124 reads (15%) | catalogued as COSV100749716; called by muse, mutect2, varscan2
- DCLK2 | c.114C>A p.G38= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99652543; called by muse, mutect2
- DENND5A | c.633A>G p.T211= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV100065074; called by muse, mutect2
- DLGAP2 | c.1530C>A p.S510= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV70104525; called by muse, mutect2, varscan2
- DLGAP4 | c.675T>C p.S225= | Silent (SNP) | VAF 51/114 reads (45%) | catalogued as rs1165370896, COSV100211493; called by muse, mutect2, varscan2
- DNAH3 | c.246C>T p.Y82= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99769526; called by muse, mutect2, varscan2
- DOP1B | c.4674C>T p.S1558= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as rs377530449; called by muse, mutect2, varscan2
- DSCAML1 | c.805C>A p.R269= (on ENST00000321322; = p.R209= on NM_020693.4) | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV100356741; called by muse, mutect2, varscan2
- E2F2 | c.156G>A p.T52= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs760250765, COSV100674849; called by muse, mutect2, varscan2
- EFCAB3 | c.462C>T p.P154= | Silent (SNP) | VAF 26/122 reads (21%) | catalogued as rs763621299, COSV100540395; called by muse, mutect2, varscan2
- ELMO1 | c.495G>A p.L165= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV100165488; called by muse, mutect2, varscan2
- ESYT2 | c.2232A>G p.P744= (on ENST00000613624; = p.P668= on NM_020728.3) | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs562066737, COSV99277098; called by muse, mutect2, varscan2
- FMO5 | c.924G>C p.T308= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV54207193; called by muse, mutect2, varscan2
- FREM1 | c.2691T>C p.P897= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as COSV101085155; called by muse, mutect2, varscan2
- GAP43 | c.42T>C p.N14= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV100525816; called by muse, mutect2, varscan2
- GLB1L3 | c.108A>G p.E36= | Silent (SNP) | VAF 19/150 reads (13%) | catalogued as rs374355226; called by muse, mutect2, varscan2
- HEATR6 | c.714A>G p.A238= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs1240963115, COSV51747839; called by muse, mutect2, varscan2
- HMGB2 | c.483A>G p.A161= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV99632779; called by muse, mutect2, varscan2
- HNF1A | c.1245G>A p.G415= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs917606298, COSV99982855; called by muse, mutect2, varscan2
- IKBKB | c.549G>T p.V183= | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as COSV100645789; called by muse, mutect2, varscan2
- KIAA0100 | c.3924G>A p.L1308= | Silent (SNP) | VAF 41/126 reads (33%) | catalogued as COSV101197373; called by muse, mutect2, varscan2
- KLHDC4 | c.936C>T p.F312= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as rs749258143, COSV54508451; called by muse, mutect2, varscan2
- KRT15 | c.645C>A p.V215= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV99563213; called by muse, mutect2, varscan2
- KRT74 | c.1125G>A p.V375= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV59773345; called by muse, mutect2, varscan2
- LARS1 | c.1405C>T p.L469= (on ENST00000394434 / NM_020117.11; = p.L442= on NM_016460.3) | Silent (SNP) | VAF 40/126 reads (32%) | catalogued as COSV99198713; called by muse, mutect2, varscan2
- LIMCH1 | c.174G>A p.L58= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as rs1490124795, COSV100574220; called by muse, mutect2, varscan2
- LZTS1 | c.1467G>T p.G489= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as COSV99743178; called by muse, mutect2, varscan2
- MACF1 | c.2431C>A p.R811= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV100485809; called by muse, mutect2, varscan2
- MARK3 | c.384C>G p.L128= | Silent (SNP) | VAF 34/120 reads (28%) | catalogued as COSV99358633; called by muse, mutect2, varscan2
- MS4A6E | c.186G>T p.L62= | Silent (SNP) | VAF 43/129 reads (33%) | catalogued as COSV100279085, COSV100279206; called by muse, mutect2, varscan2
- NADSYN1 | c.972A>G p.K324= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as COSV100034961; called by muse, mutect2, varscan2
- NBEA | c.8289C>T p.N2763= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV100082833; called by muse, mutect2, varscan2
- NIPAL4 | c.249C>A p.S83= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as rs1408588578, COSV100357262; called by muse, mutect2, varscan2
- NPAS3 | c.783T>A p.R261= (on ENST00000356141 / NM_001164749.2; = p.R229= on NM_022123.3) | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as COSV100640496; called by muse, mutect2, varscan2
- OCA2 | c.2352G>T p.L784= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100668373; called by muse, mutect2, varscan2
- OR1S2 | c.582G>A p.L194= | Silent (SNP) | VAF 22/144 reads (15%) | catalogued as COSV100224330; called by muse, mutect2, varscan2
- OR2T27 | c.246G>T p.L82= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100788332; called by muse, mutect2, varscan2
- OR3A3 | c.603C>A p.T201= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV99351483; called by muse, mutect2, varscan2
- OR52J3 | c.192C>T p.F64= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs933975345, COSV66746676; called by muse, mutect2, varscan2
- OR5H6 | c.264G>A p.S88= (on ENST00000642105; = p.S72= on NM_001005479.2) | Silent (SNP) | VAF 86/222 reads (39%) | catalogued as rs752000177, COSV101051760; called by muse, mutect2, varscan2
- P2RY13 | c.351T>C p.R117= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV99854173; called by muse, mutect2, varscan2
- PBX2 | c.1278T>C p.S426= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV100904037; called by muse, mutect2, varscan2
- PCDH7 | c.2286G>A p.Q762= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as rs1317136441; called by muse, mutect2, varscan2
- PDGFRA | c.1965G>A p.L655= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV57272642, COSV99957332; called by muse, mutect2, varscan2
- PGF | c.309C>T p.T103= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as COSV99462657; called by muse, mutect2, varscan2
- PIK3R6 | c.1275G>A p.R425= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100266758; called by muse, mutect2, varscan2
- PKHD1 | c.11178T>C p.N3726= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs1363396060, COSV100945002; called by muse, mutect2, varscan2
- PLB1 | c.114A>G p.P38= | Silent (SNP) | VAF 31/122 reads (25%) | catalogued as COSV100579607; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1041G>A p.G347= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV100982343, COSV100982563; called by muse, mutect2, varscan2
- PPP1R18 | c.879A>G p.A293= | Silent (SNP) | VAF 27/279 reads (10%) | catalogued as COSV99223834; called by muse, mutect2
- PPP2R2B | c.969C>T p.D323= (on ENST00000394409; = p.D389= on NM_181674.2) | Silent (SNP) | VAF 51/137 reads (37%) | catalogued as rs770113098, COSV100355766; called by muse, mutect2, varscan2
- PRAMEF1 | c.729T>C p.H243= | Silent (SNP) | VAF 62/297 reads (21%) | catalogued as COSV100179966; called by muse, mutect2, varscan2
- R3HDM1 | c.153G>A p.E51= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs1459115532, COSV99926579; called by muse, mutect2, varscan2
- SAP130 | c.1764A>T p.T588= | Silent (SNP) | VAF 44/90 reads (49%) | catalogued as rs1464468927, COSV99385122; called by muse, mutect2, varscan2
- SHC2 | c.1185G>T p.G395= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV52743952, COSV99199092; called by muse, mutect2, varscan2
- SHROOM3 | c.495A>T p.T165= | Silent (SNP) | VAF 31/159 reads (19%) | catalogued as COSV99934991; called by muse, mutect2, varscan2
- SIGLEC12 | c.144C>T p.Y48= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV99389513; called by muse, mutect2, varscan2
- SPINT1 | c.1260C>G p.T420= (on ENST00000344051 / NM_181642.3; = p.T404= on NM_003710.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/109 reads (31%) | catalogued as COSV100689170; called by muse, mutect2, varscan2
- STYXL2 | c.816G>T p.R272= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV99609653; called by muse, mutect2, varscan2
- SUPT16H | c.1551G>A p.L517= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as COSV53524067, COSV99360098; called by muse, mutect2, varscan2
- SYT1 | c.219G>T p.L73= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV99696792; called by muse, mutect2
- TAOK2 | c.30G>A p.L10= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV99665159; called by muse, mutect2, varscan2
- TBC1D15 | c.2055C>T p.V685= | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as rs1248171012, COSV100042113; called by muse, mutect2, varscan2
- TBL3 | c.1494A>T p.S498= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV100225021; called by muse, mutect2, varscan2
- TLE3 | c.1434G>T p.R478= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as COSV100450704; called by muse, mutect2, varscan2
- TLR10 | c.636G>A p.K212= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV100457711, COSV100457909; called by muse, mutect2, varscan2
- TRH | c.93G>A p.Q31= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs772449362, COSV57015676; called by muse, mutect2, varscan2
- TTC33 | c.522C>T p.L174= | Silent (SNP) | VAF 29/245 reads (12%) | catalogued as COSV100531997; called by muse, mutect2, varscan2
- TTC9B | c.255C>T p.I85= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV53424435, COSV99454821; called by muse, mutect2, varscan2
- WHRN | c.255G>T p.P85= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV99470521; called by muse, mutect2
- ZBED2 | c.438G>T p.V146= | Silent (SNP) | VAF 27/101 reads (27%) | catalogued as COSV99343341; called by muse, varscan2
- ZNF229 | c.492G>T p.G164= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as rs1000962016, COSV99350715; called by muse, mutect2, varscan2
- ABLIM3 | c.-1C>A | 5'UTR (SNP) | VAF 42/122 reads (34%) | catalogued as COSV100448643; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826758 A>T | 3'Flank (SNP) | VAF 36/79 reads (46%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849326 C>A | 5'Flank (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- ANKRD13D | c.*446G>A | 3'UTR (SNP) | VAF 33/159 reads (21%) | catalogued as COSV100398570; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65506173 del CTTTGCTTTGA | RNA (DEL) | VAF 8/53 reads (15%) | called by mutect2, pindel, varscan2
- BX119917.1 | n.82C>G | RNA (SNP) | VAF 16/29 reads (55%) | called by muse, varscan2
- EXOC3 | chr5:442752 C>G | 5'Flank (SNP) | VAF 34/175 reads (19%) | called by muse, mutect2
- RXRG | c.49+7675C>A | Intron (SNP) | VAF 9/39 reads (23%) | catalogued as COSV63231803; called by muse, mutect2, varscan2
- TMEM108 | c.-1C>A | 5'UTR (SNP) | VAF 7/45 reads (16%) | catalogued as COSV100419336; called by muse, mutect2, varscan2
- TPH2 | c.609-10873C>G | Intron (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100421823, COSV100422231; called by muse, mutect2, varscan2
- ZNF271P | n.1514G>A | RNA (SNP) | VAF 28/84 reads (33%) | catalogued as rs142309584; called by muse, mutect2, varscan2
